Somatic mutation profile of tumor specimen MMRF_1871_1_BM_CD138pos (aliquot MMRF_1871_1_BM_CD138pos_T1_KBS5U_L05556) from MMRF case MMRF_1871, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.4 years (25,338 days).
Specimen MMRF_1871_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 796bb3e7-49fd-48e6-97e9-100b278bce33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1871_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1871_1_PB_Whole_C3_KBS5U_L05578; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c1d1d77-cac8-44c1-ade9-ce82fecce02a

The open-access MAF lists 115 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 30, Intron 13, Silent 11, 5'UTR 5, 5'Flank 5, RNA 4, Splice Site 2, Nonsense Mutation 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 165/369 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.4084+1G>A p.X1362_splice (on ENST00000326724 / NM_001080395.3; = p.X1259_splice on NM_004920.2) | Splice Site (SNP) | VAF 21/38 reads (55%) | catalogued as rs1190394795; called by muse, mutect2, varscan2
- ACRBP | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as rs764217842, COSV99976002; called by muse, mutect2, varscan2
- ANGPT4 | c.473A>C p.N158T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV67922285, COSV67922401; called by muse, mutect2, varscan2
- ANK3 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55043261; called by muse, mutect2, varscan2
- ASTN1 | c.2636G>A p.R879Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0.077); catalogued as rs372179636; called by muse, mutect2, varscan2
- C5 | c.276G>T p.L92F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs1199947642; called by muse, mutect2, varscan2
- CPAMD8 | c.3964G>A p.V1322M (on ENST00000651564; = p.V1275M on NM_015692.5) | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781277253, COSV101488549; called by muse, mutect2, varscan2
- EPB41L5 | c.794T>C p.L265S | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55349948; called by muse, mutect2, varscan2
- GAPVD1 | c.4205C>G p.S1402C (on ENST00000394104; = p.S1411C on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762987568; called by muse, mutect2, varscan2
- IGHV2-70 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs570621406; called by muse, varscan2
- IGHV2-70 | c.54A>C p.L18F | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs187704106; called by muse, mutect2, varscan2
- IGLV3-1 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs1315687985; called by muse, mutect2
- IGLV3-1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs572010535; called by muse, mutect2
- IPO13 | c.2028+1G>A p.X676_splice | Splice Site (SNP) | VAF 21/94 reads (22%) | catalogued as rs771112995, COSV64894396; called by muse, mutect2, varscan2
- ITGB4 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as rs1339557659; called by muse, mutect2, varscan2
- KCTD10 | c.785A>G p.Q262R | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1166838154; called by muse, mutect2, varscan2
- MLLT1 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1329516093; called by muse, mutect2, varscan2
- NEU4 | c.680C>T p.A227V (on ENST00000391969 / NM_001167602.3; = p.A239V on NM_080741.4) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.035); catalogued as rs374258246; called by muse, mutect2, varscan2
- NOL7 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs750301041; called by muse, mutect2, varscan2
- NOTCH3 | c.3233G>A p.G1078D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99655400; called by muse, mutect2
- NPTX2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370691047, COSV55717424; called by muse, mutect2, varscan2
- PAX5 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.264); catalogued as COSV63912856; called by muse, mutect2, varscan2
- PCDH9 | c.2411G>T p.S804I | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV60593856; called by muse, mutect2, varscan2
- PDZRN3 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762166932, COSV55214414; called by muse, mutect2, varscan2
- RMDN3 | c.920A>C p.E307A | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs140567344; called by muse, mutect2, varscan2
- VBP1 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV53971953; called by muse, mutect2, varscan2
- ZBTB49 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs535856242; called by muse, mutect2, varscan2
- ZNF618 | c.1583G>A p.R528H (on ENST00000374126 / NM_001318042.2; = p.R435H on NM_133374.2) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs972660741; called by muse, mutect2, varscan2
- ACSM1 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AFF3 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.69); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CACNA1S | c.5347G>A p.A1783T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); called by mutect2, varscan2
- CCDC22 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2
- EBF2 | c.895C>A p.H299N | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LYPD3 | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- NAMPT | c.1286G>C p.R429P | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFIA | c.1334T>A p.M445K | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- OR7E24 | c.502T>C p.F168L | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PTGS2 | c.557T>C p.F186S | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RELL2 | c.38A>T p.H13L | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- RTF1 | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- SERPINA9 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHANK2 | c.2972A>C p.E991A | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SLC23A2 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SLC6A3 | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SVIL | c.4357C>T p.H1453Y (on ENST00000355867 / NM_021738.3; = p.H1027Y on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- APPBP2 | c.187T>C p.L63= | Silent (SNP) | VAF 20/46 reads (43%) | called by mutect2, varscan2
- ARHGEF26 | c.603G>A p.G201= | Silent (SNP) | VAF 13/204 reads (6%) | catalogued as rs760553634, COSV62852128; called by muse, mutect2
- EYA1 | c.165G>A p.T55= | Silent (SNP) | VAF 63/187 reads (34%) | catalogued as rs745425275, COSV100378754; called by muse, mutect2, varscan2
- FES | c.2181C>T p.T727= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs139396266, COSV60999607; called by muse, mutect2, varscan2
- GLYAT | c.890G>A p.*297= | Silent (SNP) | VAF 132/275 reads (48%) | catalogued as COSV53540215; called by muse, mutect2, varscan2
- IRS2 | c.1677C>A p.V559= | Silent (SNP) | VAF 57/133 reads (43%) | called by muse, mutect2, varscan2
- MYO1G | c.228C>T p.P76= | Silent (SNP) | VAF 51/148 reads (34%) | called by muse, mutect2, varscan2
- OR4K17 | c.348C>A p.V116= | Silent (SNP) | VAF 72/136 reads (53%) | catalogued as COSV100210457; called by muse, mutect2, varscan2
- PCDH15 | c.5028T>A p.T1676= | Silent (SNP) | VAF 65/145 reads (45%) | catalogued as rs775752587; called by muse, mutect2, varscan2
- PTOV1 | c.822C>T p.N274= | Silent (SNP) | VAF 100/151 reads (66%) | catalogued as rs752842898; called by muse, mutect2, varscan2
- TBC1D8 | c.3234A>G p.E1078= | Silent (SNP) | VAF 6/105 reads (6%) | called by muse, mutect2
- AC011525.1 | n.867C>A | RNA (SNP) | VAF 106/161 reads (66%) | called by muse, mutect2, varscan2
- AL772337.1 | n.369C>T | RNA (SNP) | VAF 25/98 reads (26%) | catalogued as rs1046922047; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499441 A>G | 5'Flank (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- ARL13A | c.*282T>C | 3'UTR (SNP) | VAF 90/183 reads (49%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021135 G>A | 5'Flank (SNP) | VAF 49/97 reads (51%) | catalogued as rs185015243; called by muse, varscan2
- BCL7A | chr12:122021153 G>A | 5'Flank (SNP) | VAF 42/97 reads (43%) | catalogued as COSV55847562, COSV55847818; called by muse, varscan2
- BET1 | c.*855G>A | 3'UTR (SNP) | VAF 37/105 reads (35%) | called by muse, mutect2, varscan2
- C22orf42 | c.493+70_493+73del | Intron (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- CNTN3 | c.*1648C>A | 3'UTR (SNP) | VAF 62/102 reads (61%) | called by muse, mutect2, varscan2
- COL5A1 | c.654+7387T>G | Intron (SNP) | VAF 23/224 reads (10%) | called by muse, mutect2
- DTX1 | c.-445G>A | 5'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- DTX4 | c.*3062G>C | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- ELOVL5 | c.*374T>G | 3'UTR (SNP) | VAF 35/56 reads (63%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13893597 T>G | 3'Flank (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- FAM89B | chr11:65572400 C>T | 5'Flank (SNP) | VAF 86/172 reads (50%) | called by muse, mutect2, varscan2
- FOXD1 | c.*13A>G | 3'UTR (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- GATA2 | c.*289C>T | 3'UTR (SNP) | VAF 45/64 reads (70%) | called by muse, mutect2, varscan2
- GIMAP4 | c.*553T>C | 3'UTR (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- GPI | c.122+273C>T | Intron (SNP) | VAF 129/200 reads (65%) | catalogued as rs1266177677; called by muse, mutect2, varscan2
- GPSM1 | c.1456-51T>C | Intron (SNP) | VAF 80/167 reads (48%) | called by muse, mutect2, varscan2
- GRM7 | c.*402C>T | 3'UTR (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- HDGFL3 | c.161+109A>T | Intron (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2
- HMGA2 | c.-776G>A | 5'UTR (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- HNMT | c.*834A>T | 3'UTR (SNP) | VAF 41/87 reads (47%) | catalogued as COSV54510933; called by muse, mutect2, varscan2
- ILF2 | c.-38G>C | 5'UTR (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
- IPMK | c.*1555G>A | 3'UTR (SNP) | VAF 92/209 reads (44%) | called by muse, mutect2, varscan2
- KRAS | c.*4171A>C | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- KRT7 | chr12:52233082 T>G | 5'Flank (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- KRTAP6-1 | c.*175C>T | 3'UTR (SNP) | VAF 40/111 reads (36%) | catalogued as rs974097901; called by muse, mutect2, varscan2
- LPAR3 | c.*356A>C | 3'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- LRRC7 | c.647+35430T>C | Intron (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- NACA4P | n.763G>A | RNA (SNP) | VAF 51/236 reads (22%) | called by muse, mutect2, varscan2
- NELL2 | c.*249A>C | 3'UTR (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- OBSCN | c.988+16C>T | Intron (SNP) | VAF 51/105 reads (49%) | called by muse, mutect2, varscan2
- OR9Q1 | c.*58G>A | 3'UTR (SNP) | VAF 98/190 reads (52%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1481G>A | RNA (SNP) | VAF 48/128 reads (38%) | catalogued as rs375257718; called by muse, mutect2, varscan2
- OXNAD1 | c.*1805C>T | 3'UTR (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- PCDH17 | c.*973T>G | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- PGK1 | c.*2282A>G | 3'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- PROS1 | c.*264T>C | 3'UTR (SNP) | VAF 85/123 reads (69%) | called by muse, mutect2, varscan2
- PTCHD1 | c.*9887A>G | 3'UTR (SNP) | VAF 46/120 reads (38%) | catalogued as rs1007773734; called by muse, mutect2, varscan2
- RAB11A | c.*3843G>T | 3'UTR (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.1500-34G>A | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2
- RBM33 | c.3375+15G>C | Intron (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- RNF4 | c.124+93T>G | Intron (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- SEMA5A | c.*6876T>A | 3'UTR (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- SLC8A3 | c.*414C>G | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- SLITRK1 | c.*539C>T | 3'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-2797T>G | 5'UTR (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- SOGA1 | c.*5555A>T | 3'UTR (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- TAF5L | c.972+2939A>G | Intron (SNP) | VAF 30/54 reads (56%) | catalogued as rs963575073; called by muse, mutect2, varscan2
- TBC1D4 | c.-5G>C | 5'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- TFAP2B | c.*370G>A | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- TRAF3 | c.*2939C>T | 3'UTR (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- TSPAN16 | c.603+16G>T | Intron (SNP) | VAF 21/56 reads (38%) | catalogued as rs199743487; called by muse, mutect2, varscan2
- WDR26 | c.*2558A>C | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- ZNF559 | c.-57+86T>C | Intron (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- ZNRF3 | c.*3781A>G | 3'UTR (SNP) | VAF 26/42 reads (62%) | catalogued as rs892583916; called by muse, mutect2, varscan2
